Surgical pathology report (de-identified scan), TCGA case TCGA-UT-A88E, project TCGA-MESO (Mesothelioma), tissue source site Asbestos Diseases Research Institute, specimen TCGA-UT-A88E-01B (Primary Tumor).

DOB
Sex : Male
Ph

Received
Printed

HISTOPATHOLOGY REPORT

CLINICAL NOTES:

Right pleural effusion. Probable meso. (Asbestos exposure).

MACROSCOPIC:

'Parietal pleura'. The specimen consists of multiple irregular cream membranous pieces of tissue measuring between 3mm and 17x8x5mm. Each piece bears a firm cream nodule measuring between 2mm and 9x7x5mm. Representative sections. (Block A - 4p, B and C - 3p each). PAS, DPAS requested on each block.

MICROSCOPIC:

The specimen consists of portions of pleura which include pleural fat and skeletal muscle. The pleura is markedly thickened by an epithelioid malignant infiltrate with features consistent with malignant mesothelioma of epithelial type. The malignant cells are arranged in solid sheets with areas of tubular and tubulopapillary differentiation. There is background fibromyxoid stroma. The cells have large irregular nuclei with prominent nucleoli and a variable amount of eosinophilic to slightly clear cytoplasm. The cells are poorly cohesive and shows focal clefts between many of the cell aggregates. Some of the cells have large clear cytoplasmic vacuoles.

No intracytoplasmic mucin is seen on PAS diastase stain.

Immunohistochemistry:

Calretinin, thrombomodulin, ck5/6, ck 7 positive.
CK 20, TTF-1 negative.

The microscopic features and immunohistochemical profile are consistent with malignant mesothelioma of epithelial type.

DIAGNOSIS:

RIGHT PARIETAL PLEURAL BIOPSY - MALIGNANT MESOTHELIOMA OF EPITHELIAL TYPE

Reported by

ICD-O-3

Mesothelioma epithelioid, malignant 9052/3

Site CCF

Pleura C38.4

Path

Parietal pleura C38.4

2/10/2013

Criteria	Met	No
ICDAA Discrepancy	✓	✓

Surge Use	☐
Norm	☐
No-Act File	☐
Conta Patler	☐
See Patler	☐
See FI	☐
Contlr Treatm	☐
Signe	☐
Dati	☐

Source: NCI Genomic Data Commons file 277b1d92-ae5d-4d7b-a481-24f80794e067 (TCGA-UT-A88E.BA1F0E9D-7A2A-400F-B4E5-1B5A20E3EA0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).